Somatic mutation profile of tumor specimen TCGA-DH-A7UR-01A (aliquot TCGA-DH-A7UR-01A-11D-A33T-08) from TCGA case TCGA-DH-A7UR, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 59.7 years (21,803 days).
Specimen TCGA-DH-A7UR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16e04782-9c9f-4717-b4a7-bc9120cf927d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-A7UR-10A (Blood Derived Normal), aliquot TCGA-DH-A7UR-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30449f9e-06d0-4d2b-be2e-acb9faaa8058

The open-access MAF lists 68 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 3, RNA 3, In Frame Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 46/130 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1057519906, COSV57468942, COSV57468989, COSV57477941; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.809T>G p.L270R (on ENST00000379240; = p.L295R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99733316; called by muse, mutect2, varscan2
- ADGRB1 | c.3215C>T p.T1072I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100029497; called by muse, mutect2, varscan2
- AKR1C8P | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as rs150568767; called by muse, mutect2, varscan2
- ANO9 | c.2244G>A p.W748* | Nonsense Mutation (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100229928; called by muse, mutect2, varscan2
- AREL1 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 49/131 reads (37%) | catalogued as COSV100707591; called by muse, mutect2, varscan2
- ARMH3 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV100898885; called by muse, mutect2, varscan2
- CCDC160 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.214); catalogued as COSV100892107; called by muse, mutect2
- CIC | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as rs968289754, COSV50569160; called by muse, mutect2, varscan2
- CLASP1 | c.3670C>T p.P1224S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV55316773; called by muse, mutect2, varscan2
- CRYBA1 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.027); catalogued as rs147836280; called by muse, mutect2
- CXorf58 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1026306543, COSV64858787; called by muse, mutect2
- DST | c.17361G>A p.M5787I (on ENST00000361203 / NM_001374722.1; = p.M3484I on NM_015548.5) | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV99754182; called by muse, mutect2, varscan2
- ELF1 | c.21G>C p.Q7H | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV99522969; called by muse, mutect2, varscan2
- FAM120C | c.1474T>G p.F492V | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100069890; called by muse, mutect2, varscan2
- FAT4 | c.10943G>A p.S3648N | Missense Mutation (SNP) | VAF 78/221 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV100628153; called by muse, mutect2, varscan2
- FBN3 | c.5393C>T p.S1798L | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs765678593, COSV54457690; called by muse, mutect2, varscan2
- FUBP1 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 75/121 reads (62%) | catalogued as COSV99628398; called by muse, mutect2, varscan2
- GRIA3 | c.1185+1G>T p.X395_splice | Splice Site (SNP) | VAF 86/224 reads (38%) | catalogued as COSV52076399, COSV99989676; called by muse, mutect2, varscan2
- HOXA1 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.367); catalogued as rs770180375, COSV100547347, COSV58029745; called by muse, mutect2, varscan2
- KIF20B | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV99589822; called by muse, mutect2, varscan2
- KIF5B | c.1546T>A p.Y516N | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100191760; called by muse, mutect2, varscan2
- L1CAM | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.117); catalogued as COSV100649026; called by muse, mutect2, varscan2
- LRRC14B | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV99360116; called by muse, mutect2, varscan2
- N4BP2L2 | c.133A>T p.R45* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as COSV99912500; called by muse, mutect2, varscan2
- NAP1L2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 104/291 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as COSV65172496; called by muse, mutect2, varscan2
- NOS1 | c.2608A>G p.R870G | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV100500378; called by muse, mutect2
- OR2A5 | c.914T>G p.L305W | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101278721; called by muse, mutect2
- OR4S2 | c.262A>C p.K88Q | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100412612; called by muse, mutect2, varscan2
- PCLO | c.8192G>A p.R2731H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200140697, COSV61622195; called by muse, mutect2, varscan2
- PDC | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.894); catalogued as rs372016238; called by muse, mutect2, varscan2
- PITPNM2 | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54902702, COSV99758678; called by muse, mutect2, varscan2
- PRKCI | c.882+1G>A p.X294_splice | Splice Site (SNP) | VAF 22/81 reads (27%) | catalogued as COSV99855768; called by muse, mutect2, varscan2
- QRICH2 | c.3797C>T p.A1266V | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1229645568, COSV99429066; called by muse, mutect2
- SKIDA1 | c.2623G>T p.D875Y | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV101481282; called by muse, mutect2, varscan2
- TENM3 | c.6016C>T p.R2006C | Missense Mutation (SNP) | VAF 43/478 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1242840827, COSV69313466; called by muse, mutect2
- TIGD3 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs984734277, COSV99361524; called by muse, mutect2
- TLE4 | c.1029G>T p.L343F | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV54627676, COSV99511780; called by muse, mutect2
- TNFRSF8 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.389); catalogued as COSV99821333; called by muse, mutect2, varscan2
- ARID2 | c.167_171del p.T56Rfs*8 | Frame Shift Del (DEL) | VAF 47/119 reads (39%) | called by mutect2, pindel, varscan2
- EVC2 | c.1336_1338del p.E446del | In Frame Del (DEL) | VAF 102/362 reads (28%) | called by pindel, varscan2
- MAP3K8 | c.766+4_766+7del p.X256_splice | Splice Site (DEL) | VAF 20/104 reads (19%) | called by mutect2, pindel, varscan2
- MLX | c.751_752del p.Q251Vfs*27 | Frame Shift Del (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel, varscan2
- MYO9A | c.2372del p.N791Tfs*67 | Frame Shift Del (DEL) | VAF 51/130 reads (39%) | called by mutect2, pindel, varscan2
- NAV3 | c.3844_3846del p.L1282del | In Frame Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel, varscan2
- RFC4 | c.695_696del p.K232Sfs*40 | Frame Shift Del (DEL) | VAF 16/158 reads (10%) | called by mutect2, pindel, varscan2
- TCF7L2 | c.798_801del p.P267Cfs*17 (on ENST00000355995 / NM_001367943.1; = p.P244Cfs*17 on NM_030756.5) | Frame Shift Del (DEL) | VAF 24/254 reads (9%) | called by mutect2, pindel
- USP40 | c.513_516del p.C172Kfs*14 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by pindel, varscan2
- ABCA2 | c.6168G>A p.K2056= (on ENST00000614293; = p.K2026= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/167 reads (39%) | catalogued as COSV99687424; called by muse, mutect2, varscan2
- ADAMTS12 | c.2766G>A p.P922= | Silent (SNP) | VAF 81/176 reads (46%) | catalogued as COSV61262850, COSV61263240; called by muse, mutect2, varscan2
- CENPBD1 | c.159A>G p.T53= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs370787484; called by muse, mutect2, varscan2
- EHBP1 | c.3522C>T p.R1174= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99860578; called by muse, mutect2, varscan2
- FAM13C | c.1338G>A p.E446= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV99513537; called by muse, mutect2
- FCRL4 | c.1440C>T p.S480= | Silent (SNP) | VAF 79/210 reads (38%) | catalogued as COSV99619561; called by muse, mutect2, varscan2
- HECTD2 | c.1185C>T p.I395= | Silent (SNP) | VAF 27/183 reads (15%) | catalogued as COSV53222370; called by muse, mutect2, varscan2
- MFSD5 | c.909C>T p.T303= | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs1387467871, COSV100288976; called by muse, mutect2, varscan2
- MUC3A | c.7998A>C p.G2666= | Silent (SNP) | VAF 48/929 reads (5%) | catalogued as rs765874442; called by muse, mutect2
- MYH3 | c.1404C>T p.I468= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as COSV99878042; called by muse, mutect2, varscan2
- PARK7 | c.378C>T p.H126= | Silent (SNP) | VAF 5/85 reads (6%) | catalogued as COSV100096570; called by muse, mutect2
- PTCHD1 | c.927G>A p.L309= | Silent (SNP) | VAF 74/240 reads (31%) | catalogued as rs758235274, COSV101037440; called by muse, mutect2, varscan2
- RADIL | c.816G>A p.R272= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV101271345; called by muse, mutect2
- RPTN | c.375C>T p.H125= | Silent (SNP) | VAF 43/471 reads (9%) | catalogued as rs778811948, COSV60166931, COSV60167410; called by muse, mutect2
- SEMA6B | c.1785G>A p.S595= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1299055282, COSV56703619; called by muse, mutect2, varscan2
- TRAF7 | c.1557C>T p.L519= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as COSV100399372; called by muse, mutect2
- ANKRD20A5P | n.196C>A | RNA (SNP) | VAF 10/39 reads (26%) | catalogued as rs763805243; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86028C>T | Intron (SNP) | VAF 19/257 reads (7%) | catalogued as COSV72278045; called by muse, mutect2
- UBTFL2 | n.530T>C | RNA (SNP) | VAF 14/60 reads (23%) | called by mutect2, varscan2
- UBTFL2 | n.434C>T | RNA (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
